Gene-level copy-number profile of tumor specimen HCM-BROD-0220-C15-06A from HCMI case HCM-BROD-0220-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: GX; Age at diagnosis: 60.2 years (21,985 days).
Specimen HCM-BROD-0220-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c9ea08b1-df38-4925-aaf2-637ee1b421f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0220-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,728 have no estimate.
https://portal.gdc.cancer.gov/files/e24790b0-5d2c-4237-8eac-9a05c47f6df1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 518; copy number 1: 523; copy number 2: 29,476; copy number 3: 23,337; copy number 4: 2,835; copy number 5: 954; copy number 6: 884; copy number 7: 6; copy number 10: 12; copy number 18: 62; copy number 20: 54; copy number 22: 2; copy number 24: 54; copy number 25: 4; copy number 27: 10; copy number 28: 17; copy number 29: 78; copy number 33: 3; copy number 36: 7; copy number 39: 36; copy number 125: 7; copy number 169: 6; copy number 180: 5; copy number 185: 3; copy number 192: 2.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,822,686–12,841,357, 3 genes: LINC01784, PRAMEF11, PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–1): PRAMEF2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,206 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:166,403,573–179,861,612, 236 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr2:233,059,967–233,586,291, 12 genes, copy number 10: INPP5D, RN7SL32P, ATG16L1, SCARNA5, SCARNA6, SAG, AC013726.1, DGKD, Y_RNA, USP40, PPFIA1P1, UGT1A12P.
- chr5:18,886,622–45,895,970, 344 genes, copy number 5–6 (broad region; genes not listed).
- chr6:60,719,222–61,681,049, 8 genes, copy number 5 (within-gene range 3–5): GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1.
- chr7:5,898,725–5,926,550, 1 gene, copy number 5 (within-gene range 4–5): CCZ1.
- chr7:21,215,537–62,275,678, 706 genes, copy number 6–39 (broad region; genes not listed).
- chr8:112,222,928–145,066,685, 505 genes, copy number 5 (broad region; genes not listed).
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.
- chr16:77,788,564–77,980,107, 1 gene, copy number 5 (within-gene range 3–5): VAT1L.
- chr16:77,892,422–78,066,761, 5 genes, copy number 5: PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr17:18,426,861–18,506,313, 8 genes, copy number 6: KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr17:37,907,957–41,786,931, 219 genes, copy number 18–192 (broad region; genes not listed).
- chr20:61,953,469–64,327,972, 136 genes, copy number 5 (broad region; genes not listed).
- chr21:9,975,017–13,067,033, 18 genes, copy number 5: CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.
- chr22:18,873,543–18,947,732, 5 genes, copy number 5 (within-gene range 2–5): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
